Somatic mutation profile of tumor specimen TCGA-AA-3850-01A (aliquot TCGA-AA-3850-01A-01W-0995-10) from TCGA case TCGA-AA-3850, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.2 years (27,090 days).
Specimen TCGA-AA-3850-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd2474ba-28c5-40f8-a78c-8d715bca1a45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3850-10A (Blood Derived Normal), aliquot TCGA-AA-3850-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f82fb4a9-40b8-430f-b47d-9347f392a9b7

The open-access MAF lists 127 somatic variants for this specimen: 86 protein-altering or splice-affecting, 38 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 38, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 3'Flank 1, Intron 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAM | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs121918133, CM072885, COSV99538833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 76/396 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- VPS53 | c.1516C>T p.R506* (on ENST00000571805 / NM_001366253.2; = p.R477* on NM_018289.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/111 reads (25%) | catalogued as rs200594402, CM164762, COSV52126085; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.3242T>C p.I1081T (on ENST00000272895 / NM_173076.3; = p.I763T on NM_015657.3) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99790957; called by muse, mutect2, varscan2
- ABL2 | c.1670G>A p.G557E (on ENST00000502732 / NM_007314.4; = p.G542E on NM_005158.5) | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV100772870; called by muse, mutect2, varscan2
- ACMSD | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs939826275, COSV51607557; called by muse, mutect2, varscan2
- ADAMTS18 | c.1276A>T p.T426S | Missense Mutation (SNP) | VAF 15/462 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as COSV99273525; called by muse, mutect2
- AL592490.1 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 52/478 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV101308242, COSV69428342; called by muse, mutect2, varscan2
- APC | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 20/120 reads (17%) | catalogued as CS971608, COSV57347627, COSV99970657; called by muse, mutect2, varscan2
- ARFGEF2 | c.1775-1G>A p.X592_splice | Splice Site (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100904364; called by muse, mutect2, varscan2
- CACNA1E | c.5191C>T p.R1731W | Missense Mutation (SNP) | VAF 102/454 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62415790; called by muse, mutect2, varscan2
- CACNA1G | c.5447A>G p.D1816G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100662172; called by muse, mutect2
- CAMK1D | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 157/699 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV66610050, COSV66612830; called by muse, mutect2, varscan2
- CCDC77 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs139785486; called by muse, mutect2, varscan2
- COL6A3 | c.4270C>T p.R1424C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs768522226, COSV99798394; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.2464G>T p.V822L | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101041488; called by muse, mutect2, varscan2
- DENND5B | c.2588T>C p.V863A | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV60909560; called by muse, mutect2, varscan2
- DLK1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV57991876; called by muse, mutect2, varscan2
- DOCK9 | c.2995G>A p.V999I (on ENST00000376460 / NM_001366676.2; = p.V1000I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/822 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs763105955, COSV100240032; called by muse, mutect2, varscan2
- DRGX | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753489697, COSV65136429; called by muse, mutect2, varscan2
- ELOA | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 118/584 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69310469; called by muse, mutect2, varscan2
- EP400 | c.3730G>A p.A1244T | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs912469085, COSV100201712; called by muse, mutect2, varscan2
- ERBB4 | c.2633A>T p.D878V | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100726515; called by muse, mutect2, varscan2
- FAT1 | c.9293G>C p.R3098T | Missense Mutation (SNP) | VAF 143/572 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1346353699, COSV101499117, COSV101499457; called by muse, mutect2
- FBH1 | c.998C>T p.P333L (on ENST00000362091 / NM_178150.3; = p.P384L on NM_032807.4) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs745630568, COSV100758825; called by muse, mutect2, varscan2
- FBXW7 | c.1428C>A p.S476R (on ENST00000281708 / NM_001349798.2; = p.S396R on NM_018315.5) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658966; called by muse, varscan2
- FGF1 | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 92/383 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100532432, COSV61803944; called by muse, mutect2, varscan2
- FRMD4A | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1053776268, COSV62264829; called by muse, mutect2, varscan2
- GALNT13 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 195/1268 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV101223646, COSV67222532; called by muse, mutect2, varscan2
- GRM8 | c.1379C>G p.T460S | Missense Mutation (SNP) | VAF 68/902 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV100284521; called by muse, mutect2
- H2AC4 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV52518989; called by muse, mutect2
- HMCN1 | c.13000G>A p.V4334I | Missense Mutation (SNP) | VAF 42/1712 reads (2%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as rs1327271424, COSV54936423; called by muse, mutect2
- HSPA1L | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.698); catalogued as rs142416335; called by muse, mutect2, varscan2
- KCNK9 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 29/178 reads (16%) | catalogued as COSV100271294; called by muse, mutect2, varscan2
- KRT40 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs779823166, COSV66696465; called by muse, mutect2, varscan2
- LARP1B | c.1418G>T p.R473L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV104390498, COSV52798417, COSV52803062; called by muse, mutect2, varscan2
- MACF1 | c.17228G>A p.G5743E (on ENST00000372915; = p.G3785E on NM_012090.5) | Missense Mutation (SNP) | VAF 112/616 reads (18%) | catalogued as COSV99245675; called by muse, mutect2, varscan2
- MARK4 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755396651, COSV53467322; called by muse, mutect2, varscan2
- MCTP1 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100387677; called by muse, mutect2, varscan2
- MGA | c.4009G>T p.E1337* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV99580682; called by muse, mutect2
- MIP | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs966166555, COSV57509765; called by muse, mutect2, varscan2
- NGEF | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99889913; called by muse, mutect2
- NLGN1 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64335242; called by muse, mutect2, varscan2
- OCA2 | c.573+1G>C p.X191_splice | Splice Site (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100667845, COSV100668221; called by muse, mutect2, varscan2
- OGDH | c.2989G>A p.G997S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402614488, COSV99759259; called by muse, mutect2, varscan2
- PANX2 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV50298331; called by muse, mutect2, varscan2
- PHEX | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV101039838; called by muse, mutect2, varscan2
- PLCB1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 96/385 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.346); catalogued as rs747785129, COSV62054757, COSV99059820; called by muse, mutect2, varscan2
- PLEKHO2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs143331139; called by muse, varscan2
- PPP6R2 | c.2015G>A p.R672H (on ENST00000216061 / NM_001365836.1; = p.R645H on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs148234883; called by muse, varscan2
- PSME4 | c.5413A>C p.T1805P | Missense Mutation (SNP) | VAF 103/478 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122574; called by mutect2, varscan2
- RAPGEF4 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 101/417 reads (24%) | catalogued as COSV51413829, COSV99911116; called by muse, mutect2, varscan2
- RBFOX1 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV60962022; called by muse, mutect2, varscan2
- RBM43 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 160/559 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.278); catalogued as COSV100508609; called by muse, mutect2, varscan2
- ROBO4 | c.1243T>G p.S415A | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV60624785; called by muse, mutect2, varscan2
- RYR3 | c.6670C>T p.R2224C | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1188037949, COSV63109442; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.2414G>A p.R805Q | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as rs143717547; called by muse, mutect2, varscan2
- SIAE | c.1308_1310del p.N436del | In Frame Del (DEL) | VAF 178/860 reads (21%) | catalogued as rs752182375; called by pindel, varscan2
- SLC25A13 | c.1117A>G p.N373D | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99673887; called by muse, mutect2, varscan2
- SLC9C1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 197/704 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV99998336; called by muse, mutect2, varscan2
- SLC9C2 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100876879; called by muse, mutect2, varscan2
- SLITRK1 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV65675004; called by muse, mutect2, varscan2
- SOBP | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV100433279; called by muse, mutect2, varscan2
- SRCAP | c.7142G>A p.R2381H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs765139685, COSV99350673; called by muse, mutect2, varscan2
- TACC2 | c.6883G>A p.A2295T (on ENST00000334433; = p.A373T on NM_006997.4) | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99587348; called by muse, mutect2, varscan2
- TAP1 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100841251; called by muse, mutect2, varscan2
- TNNI1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 78/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60189729; called by muse, varscan2
- TNS1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs976031308, COSV50691216; called by muse, mutect2
- TNXB | c.10939C>T p.P3647S (on ENST00000647633; = p.P3400S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV64476131; called by muse, mutect2
- TRIM51 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs775128728, COSV55266719; called by muse, mutect2, varscan2
- TRIO | c.3161A>C p.D1054A | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100710647; called by muse, mutect2, varscan2
- TTN | c.97627G>A p.E32543K (on ENST00000591111; = p.E25119K on NM_003319.4) | Missense Mutation (SNP) | VAF 37/203 reads (18%) | PolyPhen probably damaging (0.994); catalogued as rs776306284, COSV59965488; called by muse, mutect2, varscan2
- TUT4 | c.1736A>C p.E579A | Missense Mutation (SNP) | VAF 297/1210 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99932577; called by muse, mutect2, varscan2
- WDR3 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100309754; called by muse, mutect2
- WWC1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99515451; called by muse, mutect2, varscan2
- ZFHX3 | c.8147G>T p.C2716F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99213735; called by muse, mutect2
- ZNF106 | c.5618G>A p.R1873Q | Missense Mutation (SNP) | VAF 37/328 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV55520918; called by muse, mutect2, varscan2
- ZNF45 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99524195; called by muse, mutect2
- ZNF677 | c.389A>C p.H130P | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.363); catalogued as COSV100448070; called by muse, mutect2, varscan2
- AMOT | c.2548del p.L850Cfs*59 (on ENST00000371959 / NM_001113490.1; = p.L441Cfs*59 on NM_133265.3) | Frame Shift Del (DEL) | VAF 26/222 reads (12%) | called by mutect2, pindel, varscan2
- APC | c.3159del p.K1053Nfs*3 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- CDH19 | c.2127del p.P710Rfs*20 | Frame Shift Del (DEL) | VAF 58/249 reads (23%) | called by mutect2, pindel, varscan2
- NFKBIZ | c.628dup p.Q210Pfs*6 | Frame Shift Ins (INS) | VAF 14/64 reads (22%) | called by pindel, varscan2
- RIMS1 | c.224A>C p.N75T | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.074); called by mutect2, varscan2
- TGIF1 | c.321_331dup p.N111Rfs*10 (on ENST00000330513 / NM_001374396.1; = p.N131Rfs*10 on NM_003244.4) | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | called by mutect2, varscan2
- AFF2 | c.2070G>A p.L690= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV99665117; called by muse, mutect2, varscan2
- AGBL5 | c.882C>T p.P294= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs375903966; called by muse, mutect2, varscan2
- ASTN2 | c.462G>A p.A154= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs371959327; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3411G>A p.E1137= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as COSV63245328; called by muse, mutect2, varscan2
- CHST1 | c.822G>A p.T274= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs369014915, COSV57324395; called by muse, mutect2, varscan2
- COX6A2 | c.228C>T p.D76= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV54932119; called by muse, mutect2, varscan2
- DTWD2 | c.279C>T p.T93= | Silent (SNP) | VAF 102/396 reads (26%) | catalogued as rs368362806; called by muse, mutect2, varscan2
- EHD4 | c.1515G>A p.A505= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs370720124; called by muse, mutect2, varscan2
- FMNL1 | c.2616G>A p.S872= | Silent (SNP) | VAF 29/196 reads (15%) | catalogued as rs766134032, COSV58958205; called by muse, mutect2, varscan2
- GAGE2A | c.30G>A p.R10= | Silent (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- GALNT5 | c.225A>G p.K75= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV52038295; called by muse, mutect2, varscan2
- GALR1 | c.972A>G p.K324= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV55317418; called by muse, mutect2, varscan2
- GATA3 | c.147G>A p.V49= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100651117; called by muse, mutect2, varscan2
- GJB7 | c.93C>T p.F31= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs768482078, COSV51530099; called by muse, mutect2
- HELQ | c.816C>T p.A272= | Silent (SNP) | VAF 115/449 reads (26%) | catalogued as COSV99787911; called by muse, mutect2, varscan2
- KRT4 | c.945C>T p.Y315= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs778125368, COSV53406546; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAPKBP1 | c.222G>A p.L74= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs1337714955, COSV52962631; called by muse, mutect2, varscan2
- MEF2C | c.309G>A p.A103= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs567797470, COSV60931103; called by muse, mutect2, varscan2
- MYH11 | c.1341C>A p.T447= | Silent (SNP) | VAF 74/302 reads (25%) | catalogued as rs200660016, COSV55555820; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NPL | c.135C>T p.N45= | Silent (SNP) | VAF 58/373 reads (16%) | catalogued as COSV51124217; called by muse, mutect2, varscan2
- OR1M1 | c.549C>T p.P183= | Silent (SNP) | VAF 41/240 reads (17%) | catalogued as COSV70036974; called by muse, mutect2, varscan2
- OR2G6 | c.426G>A p.A142= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as rs754561742, COSV58574602; called by muse, mutect2, varscan2
- OR8B4 | c.861G>T p.S287= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV62069661, COSV62069872; called by muse, mutect2, varscan2
- PCDHB12 | c.1227G>A p.L409= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV53397442; called by muse, mutect2, varscan2
- PCSK2 | c.1725C>T p.V575= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs139585816, COSV99359045; called by muse, mutect2
- PLEKHA6 | c.3093C>T p.P1031= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs1318844099, COSV55334804; called by muse, mutect2, varscan2
- PLXNA4 | c.561G>A p.T187= | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as rs772947706, COSV58129918; called by muse, mutect2, varscan2
- PTPRJ | c.3897C>G p.V1299= | Silent (SNP) | VAF 33/741 reads (4%) | catalogued as COSV101395511; called by muse, mutect2
- RAB6C | c.12C>T p.G4= | Silent (SNP) | VAF 42/303 reads (14%) | catalogued as COSV69339532; called by muse, mutect2, varscan2
- SLIT1 | c.4017C>T p.C1339= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs777541136, COSV56590702; called by muse, mutect2, varscan2
- SPATA31D1 | c.2673A>G p.E891= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs543104488, COSV61196715, COSV61198017; called by muse, mutect2, varscan2
- ST8SIA2 | c.630C>T p.I210= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99184477; called by muse, mutect2
- SYT14 | c.168C>T p.G56= | Silent (SNP) | VAF 107/455 reads (24%) | catalogued as rs540332386, COSV55055602; called by muse, mutect2, varscan2
- TTN | c.26664G>A p.P8888= (on ENST00000591111; = p.P7961= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as rs750218480, COSV60112012; called by muse, mutect2, varscan2
- USP6 | c.222G>A p.T74= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1555593875, COSV51482624; called by muse, mutect2
- ZFAT | c.90C>T p.H30= | Silent (SNP) | VAF 218/1055 reads (21%) | catalogued as rs768351805, COSV64738856; called by muse, mutect2, varscan2
- ZFHX3 | c.8148C>T p.C2716= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99213732; called by muse, mutect2, varscan2
- ZNF618 | c.1833C>T p.I611= (on ENST00000374126 / NM_001318042.2; = p.I518= on NM_133374.2) | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as rs779538888, COSV55916995, COSV55922783; called by muse, mutect2, varscan2
- ADGRF3 | chr2:26309091 C>T | 3'Flank (SNP) | VAF 10/216 reads (5%) | catalogued as COSV100275219, COSV61052400; called by muse, mutect2
- LINC01588 | n.865C>T | RNA (SNP) | VAF 70/304 reads (23%) | catalogued as rs756539981; called by muse, mutect2
- SGCZ | c.40-298514G>C | Intron (SNP) | VAF 137/600 reads (23%) | catalogued as COSV100763089, COSV100763100; called by muse, mutect2, varscan2
